Gene-level copy-number profile of tumor specimen TCGA-LN-A49L-01A from TCGA case TCGA-LN-A49L, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 44.3 years (16,164 days).
Specimen TCGA-LN-A49L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.daced99a-f238-4884-a360-2f1bfc1d3b62.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/22172870-b817-45b6-8ba3-d60dee6ff93c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 3,485; copy number 2: 26,225; copy number 3: 18,246; copy number 4: 5,268; copy number 5: 1,841; copy number 6: 2,804; copy number 7: 1,355; copy number 8: 102; copy number 9: 174; copy number 10: 69; copy number 11: 106; copy number 12: 1; copy number 13: 1; copy number 17: 90.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49L-01A-11D-A246-01): tumor purity 0.65, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,416,805–132,646,582, 1 gene (within-gene range 0–2): GPR39.
- chr2:132,643,286–133,568,463, 8 genes (within-gene range 0–2): LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2.
- chr2:153,871,922–154,453,979, 1 gene (within-gene range 0–2): GALNT13.
- chr2:212,581,357–213,021,545, 3 genes (within-gene range 0–2): AC093865.1, LINC01878, PCED1CP.
- chr3:11,529,488–11,771,350, 4 genes (within-gene range 0–3): AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr3:50,674,927–51,384,198, 1 gene (within-gene range 0–2): DOCK3.
- chr3:50,786,674–50,877,657, 2 genes: ZNF652P1, ST13P14.
- chr4:21,843,341–21,853,188, 1 gene: KCNIP4-IT1.
- chr5:122,775,079–122,834,543, 2 genes: SNX2, AC008669.1.
- chr11:19,117,099–19,281,426, 4 genes (within-gene range 0–2): ZDHHC13, CSRP3, CSRP3-AS1, E2F8.
- chr11:34,150,987–34,358,010, 1 gene (within-gene range 0–2): ABTB2.
- chr11:34,335,118–34,336,003, 1 gene: MMADHCP2.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–2): RB1.
- chr13:48,340,797–48,578,088, 8 genes: AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr13:54,572,354–54,687,547, 1 gene (within-gene range 0–2): AL442636.1.
- chr13:98,871,742–98,950,447, 2 genes: AL161420.1, RPL7L1P12.
- chr17:72,627,231–72,644,490, 2 genes: RPL32P33, AC080037.2.
- chr17:72,663,823–72,664,152, 1 gene: RN7SKP180.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,472 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–192,957,713, 1,390 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr1:206,770,764–246,507,312, 783 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:246,321,663–248,919,946, 131 genes, copy number 5 (broad region; genes not listed).
- chr2:59,014,354–68,117,200, 175 genes, copy number 5 (broad region; genes not listed).
- chr2:68,284,171–74,942,670, 186 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:211,104,934–211,299,189, 2 genes, copy number 6: AC012491.1, RPS27P10.
- chr3:11,745–1,065,875, 14 genes, copy number 5: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P.
- chr3:136,808,551–169,663,775, 488 genes, copy number 6–9 (broad region; genes not listed).
- chr4:21,949,015–22,819,575, 7 genes, copy number 6 (within-gene range 0–6): AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6.
- chr5:45,035,199–45,895,970, 6 genes, copy number 5: AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:1,623,806–24,002,433, 350 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr6:53,794,497–55,282,620, 19 genes, copy number 6 (within-gene range 3–6): LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2.
- chr7:62,275,361–67,770,468, 202 genes, copy number 6–17 (broad region; genes not listed).
- chr7:75,899,200–77,498,965, 55 genes, copy number 6: POR, MIR4651, RPL7L1P3, SNORA14A, TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2, AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2.
- chr8:55,067,585–59,137,502, 70 genes, copy number 6 (broad region; genes not listed).
- chr8:127,072,694–127,227,541, 1 gene, copy number 6 (within-gene range 4–6): CASC19.
- chr8:127,253,213–127,670,990, 7 genes, copy number 6: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1.
- chr9:110,365,248–113,759,419, 77 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–34,875,422, 592 genes, copy number 5–11 (broad region; genes not listed).
- chr10:45,454,585–57,304,559, 176 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr10:79,892,148–83,314,475, 47 genes, copy number 5–8 (within-gene range 3–8): PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1, AL359195.1, DYDC1, DYDC2, PRXL2A, TSPAN14, AC021028.1, SH2D4B, LINC02655, RPS7P9, AC027673.1, FARSBP1, WARS2P1, RPA2P2, AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P, MARK2P15.
- chr14:48,319,068–54,902,826, 146 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr16:7,726,841–11,679,152, 95 genes, copy number 6 (broad region; genes not listed).
- chr17:39,057,019–42,745,049, 226 genes, copy number 7 (broad region; genes not listed).
- chr19:10,086,122–22,532,485, 688 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:31,100,304–38,852,347, 320 genes, copy number 5–7 (broad region; genes not listed).
- chr21:40,010,999–46,665,124, 219 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
